MMRF case MMRF_1823 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/24282f2f-6711-4a5a-bcd6-078846d6f8d4

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.2 years (18,708 days); ISS stage: II; Days to last known disease status: 1,084 days (3.0 years); Days to last follow up: 1,084 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 141 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 198 days; Days to treatment end: 198 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 293 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 714 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 888 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 888 days (2.4 years); Days to treatment end: 994 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,001 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 40.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 67.7 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 2.11 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.05 mmol/L; Albumin 24 g/L; Total Protein 12.4 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.405 mg/dL.
- Day 85 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 8.49 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 9.68 mmol/L.
- Day 161 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 8.69 mmol/L.
- Day 293 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.8 g/dL; Glucose 5.89 mmol/L.
- Day 370 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 9.85 mmol/L.
- Day 427: M Protein 0 g/dL; Immunoglobulin G 9.21 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 7.1 mmol/L.
- Day 531 (ECOG 1): M Protein 0.16 g/dL; Immunoglobulin G 10.4 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 7.98 mmol/L.
- Day 631: M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 9.34 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 9.02 mmol/L.
- Day 715: M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 13.4 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 8.25 mmol/L.
- Day 825 (ECOG 1): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 11.6 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 8.42 mmol/L.
- Day 888 (ECOG 0): M Protein 1.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 8.6 g/dL; Glucose 7.92 mmol/L.
- Day 1,001 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 40.7 g/L; Total Protein 7.3 g/dL; Glucose 9.3 mmol/L.
- Day 1,084 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 10.3 mmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Melanoma; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1823_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1823_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
